Somatic mutation profile of tumor specimen 0DWVGQ from CCDI case PBCPND, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.6 years (4,971 days).
Specimen 0DWVGQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e94bd7d-ce87-4f46-af4a-02f26660c4de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWVEN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/063b4523-90d4-4694-a8ca-090a27ec2238

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 3, Intron 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 127/304 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL18A1 | c.4711G>A p.A1571T (on ENST00000359759 / NM_130444.3; = p.A1336T on NM_030582.4) | Missense Mutation (SNP) | VAF 144/341 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs754037826; called by muse, mutect2, varscan2
- POU4F2 | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 222/482 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1407128412, COSV55585748; called by muse, mutect2, varscan2
- HELZ | c.76del p.L26Sfs*27 | Frame Shift Del (DEL) | VAF 235/341 reads (69%) | called by mutect2, pindel, varscan2
- NOBOX | c.1650G>A p.T550= | Silent (SNP) | VAF 142/449 reads (32%) | catalogued as rs758092022, COSV99779964; called by muse, mutect2, varscan2
- POM121C | c.2679C>T p.A893= (on ENST00000607367; = p.A651= on NM_001099415.3) | Silent (SNP) | VAF 241/1713 reads (14%) | catalogued as rs1251591661; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2700G>A p.T900= | Silent (SNP) | VAF 182/400 reads (46%) | catalogued as rs376958354; called by muse, mutect2, varscan2
- ELP5 | c.-74A>C | 5'UTR (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100021128; called by muse, mutect2
- GLOD4 | c.676-18G>T | Intron (SNP) | VAF 99/254 reads (39%) | called by muse, mutect2, varscan2
